Somatic mutation profile of tumor specimen TCGA-AB-2872-03A (aliquot TCGA-AB-2872-03A-01W-0732-08) from TCGA case TCGA-AB-2872, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute promyelocytic leukaemia, t(15;17)(q22;q11-12); Tissue or organ of origin: Bone marrow; Age at diagnosis: 42.3 years (15,461 days).
Specimen TCGA-AB-2872-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e84c006b-c561-4f76-82f3-ba221c284888.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2872-11A (Solid Tissue Normal), aliquot TCGA-AB-2872-11A-01W-0761-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cd78183a-e89e-4d66-9afa-b7d48de7c14f

The open-access MAF lists 10 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Splice Region 1, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GOT1L1 | c.316G>C p.V106L | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV100294355; called by mutect2, varscan2
- MACF1 | c.285C>T p.V95= | Splice Region (SNP) | VAF 26/362 reads (7%) | catalogued as COSV99240042; called by muse, mutect2
- NMUR2 | c.418G>A p.V140I | Missense Mutation (SNP) | VAF 82/209 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.5); catalogued as rs200145877, COSV54919748; called by muse, mutect2, varscan2
- SCAF8 | c.3187C>A p.P1063T | Missense Mutation (SNP) | VAF 64/188 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.761); catalogued as COSV65792041; called by muse, mutect2, varscan2
- TCL1A | c.50G>A p.R17H | Missense Mutation (SNP) | VAF 97/199 reads (49%) | SIFT tolerated (0.37); PolyPhen benign (0.019); catalogued as COSV68085318; called by muse, mutect2, varscan2
- TJAP1 | c.80G>T p.G27V | Missense Mutation (SNP) | VAF 64/190 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0.017); catalogued as COSV52501260, COSV52501893; called by muse, mutect2, varscan2
- TMEM63B | c.2296C>A p.P766T | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as COSV99441177; called by muse, mutect2, varscan2
- ZMPSTE24 | c.22G>A p.D8N | Missense Mutation (SNP) | VAF 16/172 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.023); catalogued as COSV101031881; called by muse, mutect2
- CALR | c.517dup p.T173Nfs*11 | Frame Shift Ins (INS) | VAF 72/183 reads (39%) | called by mutect2, varscan2
- ZNF783 | c.802+3652C>A | Intron (SNP) | VAF 22/58 reads (38%) | catalogued as rs370091317; called by muse, varscan2
